Somatic mutation profile of tumor specimen MP2PRT-PARWRE-TMP1-A (aliquot MP2PRT-PARWRE-TMP1-A-1-0-D-A81X-36) from MP2PRT case MP2PRT-PARWRE, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.8 years (1,017 days).
Specimen MP2PRT-PARWRE-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c4ffbd6b-fc2b-4bbc-ba08-ab6653cb5eb9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARWRE-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARWRE-NB1-A-1-0-D-A81X-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/471e380c-990c-4156-96cd-f35d2a5c9b91

The open-access MAF lists 11 somatic variants for this specimen: 9 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 7, Silent 2, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CREBBP | c.4336C>T p.R1446C | Missense Mutation (SNP) | VAF 171/233 reads (73%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs398124146, COSV52113365, COSV52115600, COSV52116725; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 145/359 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- C6orf132 | c.1666C>T p.Q556* | Nonsense Mutation (SNP) | VAF 23/656 reads (4%) | catalogued as rs1396752785; called by muse, mutect2
- IDO2 | c.407C>T p.T136M (on ENST00000389060; = p.T149M on NM_194294.2) | Missense Mutation (SNP) | VAF 103/296 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as rs369922004, COSV58431371; called by muse, mutect2, varscan2
- LILRB5 | c.1487G>A p.R496H (on ENST00000449561 / NM_001081442.3; = p.R495H on NM_006840.5) | Missense Mutation (SNP) | VAF 36/523 reads (7%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs367690586; called by muse, mutect2
- SPTLC1 | c.1286C>T p.A429V | Missense Mutation (SNP) | VAF 86/256 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.581); catalogued as rs755756616, COSV52766282; called by muse, mutect2, varscan2
- KRT6B | c.922C>T p.Q308* | Nonsense Mutation (SNP) | VAF 15/261 reads (6%) | called by muse, mutect2
- LPA | c.4384C>G p.L1462V | Missense Mutation (SNP) | VAF 25/465 reads (5%) | SIFT tolerated (0.27); PolyPhen benign (0.193); called by muse, mutect2
- OR4C12 | c.686A>T p.E229V | Missense Mutation (SNP) | VAF 109/251 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- DHX38 | c.2914C>T p.L972= | Silent (SNP) | VAF 13/420 reads (3%) | called by muse, mutect2
- NFYC | c.600G>A p.Q200= | Silent (SNP) | VAF 39/329 reads (12%) | called by muse, mutect2, varscan2
